Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6393, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6393-01A (Primary Tumor).

[page 1 of 2]
PATH. NO:

TCGA-DU-6393

NAME:

MED. REC. NO:

AGE/SEX

DOB:

COLLECT DATE:

PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, LEFT OCCIPITAL LOBE: ANAPLASTIC OLIGODENDROGLIOMA.
B. BRAIN, LEFT OCCIPITAL LOBE: ANAPLASTIC OLIGODENDROGLIOMA.

Operation/Specimen: L. occipital lobe.

Clinical History and Pre-Op Dx: L. occipital tumor.

GROSS PATHOLOGY: Received in three parts.

A. Received fresh for intraoperative consultation labeled "1", is a 3 x 1.5 x 1 cm. piece of light tan to yellow to brown tissue consistent with brain tissue. Most of the surface is smooth, but lobulated while another surface is flat and smooth and possibly represents the wall of a cyst or possibly a ventricle. All submitted in cassettes 1-3.

B. Received fresh labeled "2", are four pieces of pink-red to maroon soft tissue ranging in size from 1 x 1 x 0.5 cm. to 0.5 x 0.5 x 0.4 cm.

A portion of the tissue is used for smear preparation and frozen section and submitted in cassette 4FS. The remaining tissue is submitted in cassettes 5 and 6, another small portion is submitted for potential electron microscopy.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Smear preparation and frozen section | Round cell tumor, more likely glioma. Lymphoma cannot be ruled out.

C. Received fresh labeled "occipital tumor", are several irregular fragmented pieces of variegated tan to tan-yellow to pink and hemorrhagic and probably necrotic tissue ranging in size from 5.5 x 2.5 x 1.5 cm. to 1.1 x 1.1 x 0.7 cm. Representative sections submitted in cassettes 7-10.

MICROSCOPIC:

A and B. Both specimens reveal an aplastic proliferation of oligodendrocytes with different degrees of cellularity and cytological

[page 2 of 2]
atypia. In some areas, the tumor is well differentiated and the neoplastic cells display well defined cell borders and typical perinuclear halos. In these areas, the cellularity is low and there is no significant mitotic activity. However, most of the tumor consists of areas of higher cellularity, with more pronounced nuclear pleomorphism and readily identified mitotic figures. The stromal vessels in these areas display endothelial hyperplasia. Except for one area present in the frozen section control slide, there are no extensive foci of necrosis. The tumor infiltrates the cortex in many areas and reveals neoplastic satellitosis around non-neoplastic cortical neurons. There is also evidence of previous hemorrhage within the tumor and numerous interstitial calcifications are also present. In some areas, the

tumor

completely replaces the entire gyri and produces subpial aggregates on adjacent gyri.

In summary, the findings are those of an anaplastic oligodendroglioma. The grade in the tumor is anaplastic as based on the high degree of cellularity, nuclear pleomorphism and mitotic activity in several areas

of the tumor. In the Smith Grading System for oligodendrogliomas, these areas of anaplasia would received a Grade C-D. Immunoperoxidase stain for monoclonal antibody MID-1 is pending and will be reported separately.

ADDENDUM REPORT

Immunostain with monoclonal antibody MIB-1 shows a variable, but in general high nuclear labelling index in this tumor. In areas, the index is as high as 25%, whereas in other, better differentiated areas, the nuclear index is about 10 to 12%.

Source: NCI Genomic Data Commons file e28066f4-76f2-464e-941b-a4b04703e95d (TCGA-DU-6393.13D53E5B-0FF2-4903-91A4-B183B2A4FD62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).